Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25O, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25O-01A (Primary Tumor).

[page 1 of 2]
CONFLICT		Yes	No

FINAL DIAGNOSIS -----

TOTAL THYROIDECTOMY AND CENTRAL NODE:

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Left lobe

HISTOLOGIC TYPE: Papillary carcinoma

TUMOR SIZE: Greatest dimension: 2.3 cm

FOCALITY: Unifocal

LYMPH NODES:

Metastatic carcinoma in 2 of 5 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2cm BUT <4cm

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI nodes

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS:

Focally involved by invasive carcinoma (posterior left lower lobe, (slide 1F). All other margins are negative for tumor.

VENOUS/LYMPHATIC INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Adenomatoid nodule, right lobe

NOTE: THIS CASE WAS SHOWN AT THE -

100-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9
w 5/4/11

[page 2 of 2]
PART #1: TOTAL THYROIDECTOMY & CENTRAL NODE

Dictated:

The specimen is received fresh labeled with the patient's name, xxxx, and designated 'total thyroidectomy and central node'. It consists of a total thyroidectomy specimen weighing 37.4 gms. The left lobe measures 2.8 x 2.0 x 1.8 cm. The right lobe measures 6.5 x 3.2 x 1.9 cm, and the isthmus measures 1.0 x 1.0 x 0.3 cm. There is a suture on the specimen, marking the left thyroid nodule. The specimen is inked as follows: anterior-black, posterior-orange. The specimen is serially sectioned to reveal a white tan nodule within the left lower lobe measuring 2.3 x 2.0 x 2.0 cm. The nodule grossly abuts the ink resection margin. Within the right middle to lower lobe, A second nodule is identified with a soft red tan cut surface. This nodule measures 2.1 x 1.6 x 3 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

- 1 - A - 3 (LEFT UPPER LOBE)
- 1 - B - 2 (LEFT UPPER LOBE)
- 1 - C - 1 (LEFT LOBE)
- 6 - D-I - 1 EA. (LEFT LOWER LOBE WITH NODULE)
- 1 - J - 3 (LEFT LOWER LOBE)
- 1 - K - 3 (ISTHMUS)
- 1 - L - 4 (RIGHT UPPER LOBE)
- 1 - M - 2 (RIGHT UPPER LOBE)
- 1 - N - 2 (RIGHT LOBE)
- 8 - O-V - 1 EA. (RIGHT LOBE NODULE)
- 22 - TOTAL - M

Source: NCI Genomic Data Commons file 439ad244-7a32-441c-b93a-0fe232f0e8be (TCGA-ET-A25O.666D675C-FA0F-4CF6-90AE-7B2E442D039B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).